Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TQ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TQ-01A (Primary Tumor).

ICD-O-3
Lymphoma, diffuse large B cell (HGS)
91080/3
Site: lymph node, inguinal
C77.4
YD 5/31/14

LEFT INGUINAL LYMPH NODE:

Multiples tissue fragments, which measure 3,4 x 2,8 x 0,6 cm.

INGUINAL LEFT LYMPH NODE (EXCISION):

- DIFFUSE LARGE B-CELL LYMPHOMA

The sections correspond to a lymph node which shows a complete deletion of the architecture by a vaguely nodular proliferation with extensively diffuse areas. The tumor is composed of a monotonous proliferation of atypical large cells of centroblastic type with mitotic and apoptotic figures.

The immunohistochemistry study has shown positivity of atypical large cells for CD20, CD79a, CD10, bcl-6 and bcl-2, and negativity for MUM1. Stains for follicular dendritic cells (CD21, CD35) highlight the diffuse growth of the neoplasia. There is a moderate expansion of T cells positive for CD3 and CD5. The Ki67 proliferation index is higher than 80%.

FISH: A rearrangement of the MYC gene has been found.

END

Source: NCI Genomic Data Commons file 139dc9ae-089b-4b68-a7c2-751d89eec858 (TCGA-GS-A9TQ.FA3E9D38-9A2D-43EC-AEBD-DDDA323F8BB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).